Surgical pathology report (de-identified scan), TCGA case TCGA-P5-A72Z, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Cureline, specimen TCGA-P5-A72Z-01A (Primary Tumor).

ICD-O-3
Oligodendroglioma, grade III
9451/3
Site Brain, supratentorial NOS
C71.2
JW 8/15/13

Case #

Patient: Age (years): Gender:

Clinical diagnosis: Brain tumor

Date of procurement:

Sample:

Gross description:

The material presented by soft gray-whitish pieces from right temporal lobe

Microscopic description:

Received material is represented by brain tissue consistent with anaplastic oligodendroglioma, Ki 67 up to 15%.

Final diagnosis: Anaplastic oligodendroglioma: Grade III

Confidential

Source: NCI Genomic Data Commons file a6e4bf10-81b4-4316-816c-c7ce46b528f5 (TCGA-P5-A72Z.99B1BF7C-E68F-4546-B13B-BF603738796C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).